Surgical pathology report (de-identified scan), TCGA case TCGA-06-0219, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0219-01A (Primary Tumor).

[page 1 of 2]
PATH.NO:

TCGA-06-0219

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, RIGHT TEMPORAL LOBE, EXCISIONAL BIOPSY: LOW HISTOLOGICAL GRADE GLIOMA, CONSISTENT WITH ASTROCYTOMA.
- B. BRAIN, RIGHT TEMPORAL LOBE, EXCISIONAL: ATROCYTOMA, FIBRILLARY, MIB-1 PROLIFERATION INDEX 1.5%.
- C. BRAIN, SITE NOT SPECIFIED, EXCISIONAL BIOPSY: HIGH HISTOLOGICAL GRADE ASTROCYTOMA. MIB-1 PROLIFERATION INDEX 9%.

SEE MICROSCOPIC DESCRIPTION AND COMMENT.

Operation/Specimen: Brain tumor

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

- A.
SPECIMEN: Right temporal lobe.
FIXATIVE: Formalin.
GENERAL: A tan-brown, soft tissue fragment, 1 cm in greatest dimesion.
In total, #1.

INTRAOPERATIVE CONSULTATION: Brain, temporal lobe: atypical glial proliferation, consistent with glioma.

- B.
SPECIMEN: Right temporal lobe.
FIXATIVE: Formalin.
GENERAL: Pale white, oval brain tissue fragment, 5 x 4 cm in size.
The meningeal surface has tan-brown, sulci and gyri, the resected surface has varigated papillary appearance. Serial sectioning reveals relatively normal appearing cortex, the cerebral white matter shows fine punctate markings.
SECTIONS: 2-5, representative.

- C.
SPECIMEN: Brain tumor.
FIXATIVE: Formalin.
GENERAL: Four irregular, tan-white, soft tissue fragments, 3-5 mm in greatest dimension.
SECTIONS: 6, all submitted.

MICROSCOPIC: A. Portions of cerebral cortex with moderately increased cellularity due to the presence of small round and elongated hyperchromatic nuclei. Around vessels there are accumulations of these nuclei cuffing the vessels. In these zones the neoplastic cells have a definite astrocytic phenotype. There are no mitoses, microvascular

[page 2 of 2]
cellular proliferation or necrosis.

TCGA-06-0219

B. Portions of cerebral cortex and adjacent white matter and leptomeninges. The white matter contains a neoplastic proliferation of glial cells similar to the ones described for part A. The neoplastic nuclei are round or elongated, have moderate pleomorphism, and infiltrate the cerebral cortex. Around vessels, the neoplastic cells form nests of prominently fibrillary astrocytes. In the cerebral cortex at the pial-glial interface they accumulate focally. A couple of nests of neoplastic cells are observed in the leptomeningeal space. There are no mitoses, microvascular cellular proliferation, or areas of necrosis. The neoplasm is present in the deeper margin of the white matter throughout the specimen.

C. Portions of cerebral cortex and adjacent white matter. The tissue is infiltrated by a glial neoplasm similar to that one described for parts A and B. In this specimen, however, there is a focal area of solid neoplasm, which is more cellular and contains proliferative microvessels. A couple of these microvessels have microvascular cellular proliferation, and one microvessel has undergone necrosis and thrombosis, and the immediately surrounding tumor tissue is undergoing necrosis with pseudopallading. One mitotic figure is identified.

SPECIAL STAINS: Immunoperoxidase stains for GFAP and MIB1 are performed on blocks 2 and 6.

The [REDACTED] demonstrates the strong fibrillary component of the tumor cells around vessels (#2), and in solid tumor (#6). With the MIB-1 proliferation indices of 1.5% and 9% are determined in specimen B and C, respectively.

COMMENT: In parts A and B (right temporal lobe) there is a diffusely infiltrating glioma involving white and gray matter. The neoplasm has moderate nuclear atypia, is devoid of mitotic figures, microvascular cellular proliferation, and/or necrosis, and particularly in perivascular areas has a well defined astrocytic phenotype. This neoplasm has a MIB-1 proliferation index of 1.5%. A couple of small fragments of similar neoplasm is observed in the leptomeningeal space. These are features of a histologically low grade (WHO grade II/IV) astrocytoma. In specimen C there is a similar neoplasm. However, in here there is a zone of solid tumor in which cellularity is prominent, a couple of microvessels have microvascular cellular proliferation, one microvessel has undergone necrosis and is surrounded by a microscopic zone of tumor necrosis, and one mitotic figure is observed. The MIB-1 proliferation index in this specimen is 9%. These morphological findings are those of a high histological grade glioma, possibly a glioblastoma multiforme. The specimen is small, and may not be representative of the entire lesion. The morphological findings may be correlated with clinical, imaging, and intraoperative findings for final determination.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 2ecc89e0-9595-49d7-9abb-8e368ccf51d1 (TCGA-06-0219.90027ED9-92A4-4326-A531-BE06DB61E922.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).